Gene-level copy-number profile of tumor specimen TCGA-FD-A3SL-01A from TCGA case TCGA-FD-A3SL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.3 years (22,020 days).
Specimen TCGA-FD-A3SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fa28acf8-f340-4e57-a441-bada5d636d83.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3SL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c90e539a-b7a3-4d3a-bba1-9ad622279a4a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,344; copy number 2: 41,327; copy number 3: 5,701; copy number 4: 953; copy number 5: 273; copy number 6: 43; copy number 7: 56; copy number 8: 116.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3SL-01A-21D-A22Y-01): tumor purity 0.42, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 488 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:8,501,807–22,670,711, 243 genes, copy number 5–8 (broad region; genes not listed).
- chr20:33,079,644–34,927,962, 62 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr21:10,328,411–18,760,320, 124 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr21:35,713,139–37,661,496, 58 genes, copy number 6–7: AF015720.1, MIR802, RPS20P1, PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2, MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.3, AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1.
- chr21:37,717,102–37,719,569, 1 gene, copy number 7: KCNJ6-AS1.

Autosomal genes at a single copy (total copy number 1): 8,991. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
